Somatic mutation profile of tumor specimen C3N-01200-03 (aliquot CPT0075140012) from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0688d802-a3d4-4f5e-9ee9-bed6f921b9bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01200-71 (Blood Derived Normal), aliquot CPT0075240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06dd95d6-79fc-477e-b3f0-6df9b73ad062

The open-access MAF lists 94 somatic variants for this specimen: 51 protein-altering or splice-affecting, 25 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 25, Intron 12, Frame Shift Del 4, 3'UTR 4, Frame Shift Ins 3, In Frame Del 2, Nonsense Mutation 1, Splice Site 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.758dup p.T254Dfs*30 | Frame Shift Ins (INS) | VAF 102/329 reads (31%) | catalogued as rs1553645591; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP1A3 | c.1778C>G p.S593C (on ENST00000545399 / NM_001256214.2; = p.S580C on NM_152296.5) | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487252; called by muse, mutect2, varscan2
- ATXN2 | c.3374C>A p.S1125Y (on ENST00000550104; = p.S965Y on NM_002973.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as CM1413579; called by muse, mutect2, varscan2
- BTBD3 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs759996580; called by muse, mutect2, varscan2
- COL18A1 | c.2855C>T p.P952L (on ENST00000359759 / NM_130444.3; = p.P717L on NM_030582.4) | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs750422215; called by muse, mutect2
- CZIB | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs562231137; called by muse, mutect2, varscan2
- EEA1 | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1172307888; called by muse, mutect2, varscan2
- GLRA3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- MBP | c.562C>T p.R188W (on ENST00000355994 / NM_001025101.2; = p.R55W on NM_002385.3) | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766571087; called by muse, varscan2
- MICAL2 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- SLC19A1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs776173955, COSV60756989; called by muse, mutect2, varscan2
- CASD1 | c.2264T>C p.I755T | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASK | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CSMD3 | c.9249T>A p.D3083E (on ENST00000297405 / NM_001363185.1; = p.D2914E on NM_052900.3) | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLAT | c.381+2T>C p.X127_splice | Splice Site (SNP) | VAF 57/211 reads (27%) | called by mutect2, varscan2
- DNAH11 | c.11714del p.G3905Vfs*12 | Frame Shift Del (DEL) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7391del p.G2464Afs*2 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- ECI2 | c.1175C>G p.S392* (on ENST00000380118 / NM_206836.3; = p.S362* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ESS2 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.185); called by muse, mutect2
- FOXB2 | c.599dup p.Q201Afs*73 | Frame Shift Ins (INS) | VAF 42/127 reads (33%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.380_406del p.A127_G135del | In Frame Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel
- GZF1 | c.619A>C p.K207Q | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGDCC4 | c.1801A>C p.I601L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNG2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KIFAP3 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LCE3A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MEF2D | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 21/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- MIEF2 | c.1097G>C p.G366A | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MSH3 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFATC2 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NNT | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2
- PANK4 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PLA2G3 | c.1091T>G p.F364C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PMFBP1 | c.860G>A p.C287Y | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- POLE | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RALGAPA1 | c.5306T>G p.L1769R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, varscan2
- REM1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SALL3 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCAMP3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNX5 | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPANXN5 | c.154_156del p.L52del | In Frame Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- SPART | c.783del p.L262* | Frame Shift Del (DEL) | VAF 17/153 reads (11%) | called by mutect2, pindel, varscan2
- SPATS2 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- VHL | c.610_614del p.E204Hfs*50 | Frame Shift Del (DEL) | VAF 84/336 reads (25%) | called by mutect2, pindel, varscan2
- VPS35 | c.1499_1500dup p.E501Lfs*9 | Frame Shift Ins (INS) | VAF 40/246 reads (16%) | called by mutect2, pindel, varscan2
- WDR6 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF236 | c.4288C>T p.P1430S | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.152); called by muse, mutect2
- ZNF256 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF470 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AAAS | c.408C>T p.S136= | Silent (SNP) | VAF 24/448 reads (5%) | catalogued as rs369423425; called by muse, mutect2
- ADCY6 | c.2322C>A p.A774= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs1362941438; called by muse, mutect2, varscan2
- AHNAK | c.6627A>T p.V2209= | Silent (SNP) | VAF 76/374 reads (20%) | called by muse, mutect2, varscan2
- CDK11B | c.1002G>A p.E334= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs1279885928; called by mutect2, varscan2
- CENPE | c.2013A>G p.L671= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV99477122; called by muse, mutect2, varscan2
- CORT | c.15C>T p.P5= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs375806455; called by muse, mutect2
- F5 | c.1590C>T p.S530= | Silent (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- FMN2 | c.1119C>T p.D373= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- FN1 | c.5517G>A p.E1839= | Silent (SNP) | VAF 17/355 reads (5%) | called by muse, mutect2
- GRXCR2 | c.678C>G p.S226= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- IFIH1 | c.2532G>A p.E844= | Silent (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- ITPKB | c.978G>A p.P326= | Silent (SNP) | VAF 25/384 reads (7%) | catalogued as rs1159881625, COSV55271119; called by muse, mutect2
- KCNG2 | c.1254G>A p.Q418= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- LATS1 | c.3306T>A p.I1102= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, varscan2
- MANBA | c.1452C>T p.Y484= (on ENST00000642252; = p.Y438= on NM_005908.4) | Silent (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- MFSD6 | c.1326C>T p.L442= | Silent (SNP) | VAF 61/172 reads (35%) | called by muse, mutect2, varscan2
- MS4A4E | c.126G>A p.R42= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs267603050; called by muse, mutect2, varscan2
- PAK4 | c.939C>T p.D313= | Silent (SNP) | VAF 97/348 reads (28%) | catalogued as rs369018322; called by muse, mutect2
- PLEKHA4 | c.441G>T p.A147= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as rs1404611123; called by muse, mutect2, varscan2
- PLXDC2 | c.1395C>A p.L465= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV65904134; called by muse, mutect2, varscan2
- RFTN1 | c.1422A>G p.A474= | Silent (SNP) | VAF 28/405 reads (7%) | called by muse, mutect2
- TRAFD1 | c.498C>G p.S166= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- TTN | c.84165A>C p.T28055= (on ENST00000591111; = p.T20631= on NM_003319.4) | Silent (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- VASP | c.1035G>A p.Q345= | Silent (SNP) | VAF 22/266 reads (8%) | catalogued as rs779507656; called by muse, mutect2
- VEZF1 | c.348C>A p.I116= | Silent (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- AC106741.1 | c.*39G>T | 3'UTR (SNP) | VAF 27/133 reads (20%) | catalogued as rs1339151046; called by muse, mutect2, varscan2
- CD320 | c.*205G>C | 3'UTR (SNP) | VAF 92/268 reads (34%) | called by muse, mutect2, varscan2
- FAM193B | c.1076+18A>C | Intron (SNP) | VAF 57/281 reads (20%) | called by muse, mutect2, varscan2
- FGFR4 | c.1057+165_1057+166del | Intron (DEL) | VAF 90/492 reads (18%) | called by pindel, varscan2
- HBD | c.-29+230G>C | Intron (SNP) | VAF 41/176 reads (23%) | called by muse, mutect2, varscan2
- LINC02694 | n.107A>C | RNA (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- MT1G | c.97+82_97+84del | Intron (DEL) | VAF 41/218 reads (19%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.210-29G>T | Intron (SNP) | VAF 54/242 reads (22%) | called by muse, mutect2, varscan2
- RPL4 | c.-24G>A | 5'UTR (SNP) | VAF 17/132 reads (13%) | catalogued as rs371027636; called by muse, mutect2, varscan2
- RTN4R | c.23-414C>A | Intron (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*1609T>C | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- SLC2A1 | c.868-50del | Intron (DEL) | VAF 32/242 reads (13%) | called by mutect2, pindel, varscan2
- SLC6A13 | c.202+33C>G | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- TCOF1 | c.1279-23C>G | Intron (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- TMEM134 | c.329+28C>T | Intron (SNP) | VAF 20/190 reads (11%) | catalogued as rs201248558; called by muse, mutect2, varscan2
- TMEM258 | c.3+19G>T | Intron (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
- VAPB | c.*4774A>G | 3'UTR (SNP) | VAF 63/318 reads (20%) | catalogued as COSV55666798; called by muse, mutect2, varscan2
- ZEB1 | c.58+43636G>T | Intron (SNP) | VAF 49/194 reads (25%) | called by muse, mutect2, varscan2
